Surgical pathology report (de-identified scan), TCGA case TCGA-GU-AATP, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - UT Southwestern Medical Center at Dallas, specimen TCGA-GU-AATP-01A (Primary Tumor).

[page 1 of 6]
Results

BIOPSY OR SURGICAL SPECIMEN (Order

Patient Information

Patient Name

MRN

Sex

DOB

Result Information

Status

Final result

Provider Status

Reviewed

Entry Date

Component Results

Component

Surgical Pathology

Lab

Patient Name:

Med Rec #:

Accession #:

ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site: Bladder, lateral wall
C67.2
J 4/30/14

FINAL PATHOLOGICAL DIAGNOSIS

A. Right distal ureter margin, biopsy:

- Segment of ureter, negative for tumor
- Frozen section diagnosis confirmed

B. Left distal ureter margin, biopsy:

- Focal urothelial atypia, suspicious for carcinoma in situ in cryostat sections
- Prominent sections predominantly denuded

C. Urinary Bladder and prostate, radical cystoprostatectomy:

- Invasive high grade urothelial carcinoma, involving right superior lateral bladder wall as a pedunculated mass
- Urothelial carcinoma focally invades superficial muscularis propria (pT2a)
- Lymphovascular invasion identified
- All assessed surgical resection margins are free of urothelial carcinoma
- Background urothelium with urothelial carcinoma in-situ
- Separate focus of prostatic urethral urothelial carcinoma with invasion into the subepithelial connective tissue (pT1)
- Prostate gland with nodular hyperplasia and atrophy
- Three lymph nodes, negative for carcinoma (0/3)
- See CAP template below for further details

D. Left distal ureter margin 2, biopsy:

- Segment of benign ureter
- No carcinoma is seen
- Frozen section diagnosis confirmed

E. Right obturator lymph nodes, lymphadenectomy:

- One out of three lymph nodes with isolated tumor cell clusters (1/3, micrometastasis)
- Immunohistochemical stains with appropriate control for keratin (AE1/AE3) supports this diagnosis

F. Right iliac lymph nodes, lymphadenectomy:

[page 2 of 6]
- Two out of twelve lymph nodes with metastatic carcinoma (2/12, 3mm focus in 1 node and 2nd node with isolated tumor cell)

G. Left iliac lymph nodes, lymphadenectomy:

- Two benign lymph nodes, negative for carcinoma (0/2)

H. Left obturator lymph nodes, lymphadenectomy:

- Four benign lymph nodes, negative for carcinoma (0/4)

CAP Template for Carcinoma of Urinary Bladder:

Procedure: Radical cystoprostatectomy

Tumor Site: Right superior lateral bladder wall

Tumor Size:

Greatest dimension: 1.5 x 1.5 cm (gross measurement)

Histologic Type: Urothelial (transitional cell) carcinoma

Associated Epithelial Lesions: None identified

Histologic Grade:

Urothelial Carcinoma (WHO 2004/ISUP): High-grade

Tumor Configuration: pedunculated

Microscopic Tumor Extension: Tumor invades muscularis propria

Margins: Margins uninvolved by invasive carcinoma

Lymph-Vascular Invasion: Present

Pathologic Staging (pTNM):

Primary Tumor (pT): pT2a: Tumor invades superficial muscularis propria / detrusor muscle (inner half)

Regional Lymph Nodes (pN): pN2: Multiple regional lymph node metastasis in the true pelvis

Specify: Number

examined: 24 (see specimen C, E-H)

Specify: Number

Involved: 3 (3 mm largest focus and 2 with isolated tumor cells)

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings:

Focus of prostatic urethral with invasion into the subepithelial connective tissue (pT1)

Prostate: nodular hyperplasia

Urothelial carcinoma in-situ, regenerative and biopsy site changes

Ancillary Studies: Blocks C1-3 and C4-6, C7-9 can be used for additional studies if needed.

***Electronically Signed Out By

[page 3 of 6]
CLINICAL HISTORY

Bladder cancer

Radical cystectomy, ileal conduit

SPECIMEN(S) RECEIVED

A: Right distal ureter margin

B: Left distal ureter margin

C: Bladder and prostate

D: Left distal ureter margin

E: Right obturator lymph nodes

F: Right iliac lymph node

G: Left iliac lymph nodes

H: Left obturator lymph nodes

GROSS DESCRIPTION

Specimen A is received fresh for frozen section labeled with the patient's name and "right distal ureter margin". The specimen consists of a segment of ureter measuring 0.5 cm in diameter x 0.2 cm in length. The specimen is completely submitted for frozen section as A1.

Specimen B is received fresh for frozen section labeled with the patient's name and "left distal ureter margin". The specimen consists of a segment of ureter measuring 0.4 cm in diameter x 0.3 cm in length. The specimen is completely submitted for frozen section as B1.

Specimen C:

Type of specimen: Urinary bladder, ureter stumps, prostate, seminal vesicles, vas deferens

The patient's name and case number on the specimen container match the accompanying paperwork and cassettes.

Procedure: Radical cystoprostatectomy

Fixative: Fresh. Tissue taken for research and later submitted in formalin

Dimensions: Bladder, SI 3.7 cm, left to right 4.0 cm, AP 3.5 cm, right ureter 2.3 cm in length 0.4 cm in diameter, left ureter 2.8 cm in length 0.4 cm in diameter, prostate SI 5.3 cm, left to right 6.3 cm, AP 5.5 cm

Description of findings:

Tumor: Along the right superior lateral wall is a red-brown, firm pedunculated mass measuring 1.5 x 1.5 x 1.2 cm. Surrounding the mass is an area of dark red edema measuring 3.5 x 1.5 cm. This area of edema surrounds the right ureteral orifice at the posterior wall is eroded, flattened firm measuring approximately 3.0 x 2.0 cm which is adjacent to the left ureteral orifice. Sectioning through the mass reveals invasion into the lamina propria. No definite invasion into the muscularis propria is identified. Upon sectioning through the mass, the mass fragmented from the bladder mucosa. Sectioning through the areas of edema and flattened mucosa reveals no evidence of invasion

Uninvolved mucosa: There is very little normal mucosa present. No other discrete masses or lesions are identified.

Prostate, seminal vesicles and vasa deferentia: Sectioning through the prostate reveals a pale tan to yellow multinodular architecture with multiple cystic areas ranging in size up to 0.3 cm in diameter. A discrete nodular mass is not grossly identified. The seminal vesicles and vas deferens are unremarkable.

Additional findings: Four possible lymph nodes are identified ranging from 0.3 to 0.5 cm in greatest dimension.

Ink code: Right prostate orange, left prostate blue, anterior bladder green, posterior bladder black.

Section key:

C1 right ureter longitudinal section including attached bladder mucosal edema

[page 4 of 6]
C2 left ureter longitudinal section including adjacent flattened bladder mucosa
C3-C6 pedunculated mass completely submitted
C7, C8 edema adjacent to mass
C9 right wall and posterior wall including flattened mucosa
C10- left wall and posterior wall including flattened mucosa
C11 representative section of anterior wall
C12 representative section of dome
C13, C14 one complete cross section extending from bladder neck to prostate apex split
C15 urethral margin submitted en face
C16, C17 right apex
C18-C20 representative sections of right prostate
C21, C22 left apex
C23, C24 representative section of left prostate
C25
C26 representative sections of right and left distal vas deferens
C27 possible lymph nodes

Specimen D is received fresh for frozen section labeled with the patient's name and "left distal ureter margin". The specimen consists of a segment of ureter measuring 0.5 cm in diameter x 0.3 cm in length. The specimen is completely submitted for frozen section as D1.

Specimen E is received in formalin labeled with the patient's name and "right obturator lymph nodes". The specimen consists of an aggregate of yellow fatty tissue measuring 5.5 x 2.7 x 1.5 cm. Three possible lymph nodes are identified measuring from 1.0 up to 5.5 cm in greatest dimension which are completely submitted.

Section key:

E1-E6 largest lymph node sectioned
E7 one lymph node bisected
E8 one lymph node bisected

Specimen F is received in formalin labeled with the patient's name and "right iliac lymph nodes". The specimen consists of an aggregate of yellow fatty tissue measuring 5.5 x 5.0 x 3.5 cm. Multiple lymph nodes are identified ranging from 0.3 up to 2.4 cm in greatest dimension which are completely as follows:

F1-F4 largest lymph node sectioned
F5, F6 one lymph node trisected
F7 one lymph node
F8 one lymph node bisected
F9 one lymph node bisected
F10 one lymph node trisected
F11, F12 multiple single lymph nodes

Specimen G is received in formalin labeled with the patient's name and "left iliac lymph nodes". The specimen consists of an aggregate of yellow fatty tissue measuring 5.0 x 3.5 x 3.0 cm. Two possible lymph nodes are identified ranging from 0.8 up to 2.5 cm in greatest dimension which are completely submitted as follows:

G1, G2 larger lymph node bisected
G3 smaller lymph node

Specimen H is received in formalin labeled with the patient's name and "left obturator lymph nodes". The specimen consists of an aggregate of yellow fatty tissue measuring 4.5 x 4.0 x 1.5 cm. Multiple possible lymph nodes are identified ranging from 0.5 up to 3.5 cm in greatest dimension which are completely submitted as follows:

H1-H3 largest lymph sectioned
H4 one lymph node bisected

[page 5 of 6]
H5 three single lymph nodes

MICROSCOPIC DESCRIPTION

The stain quality is acceptable.

A-H. The microscopic findings are reflected in the diagnoses rendered.

INTRAOPERATIVE CONSULT DIAGNOSIS

Time in: Time out:
A1-FS, Right distal ureter margin, biopsy: "Negative for tumor"

Time in: Time out:
B1-FS, Left distal ureter margin, biopsy: "Atypical urothelium,
suspicious for CIS. Request more tissue".

Time in: Time out:
D1-FS, Left distal ureter margin, frozen: "Negative for tumor.
Predominantly denuded".

Reported to by [REDACTED]

Interpretation performed at:

Results

Pathology Report - Scan on [REDACTED]: Intraoperative consultation report

Result History

BIOPSY OR SURGICAL SPECIMEN ([REDACTED]) - Order Result History Report.

Collection Information

Date and Time

Accession #

Lab Information

Status:

This order is currently not shared in

Order

BIOPSY OR SURGICAL SPECIMEN ([REDACTED])

Patient Information

[page 6 of 6]
Patient Name _____

MRN
[REDACTED]

Sex
[REDACTED]

DOB
[REDACTED]

Visit Information

Date	Time	Department	Provider
	[REDACTED]	Urology	

Admission Information

Attending Provider	Admitting Provider	Admission Type	Admission Date/Time
Discharge Date	Hospital Service	Auth/Cert Status	Service Area
Unit	Room/Bed	Admission Status Unknown Status (No Confirmation Status)	

Date and Time [REDACTED]	Ordering	Authorizing	Department Urology
-----------------------------	----------	-------------	-----------------------

Order

Order Name BIOPSY OR SURGICAL SPECIMEN	Code [REDACTED]	Order Number [REDACTED]
---	--------------------	----------------------------

Discharge Information

Discharge Provider (none)	Date/Time (none)	Disposition (none)	Destination (none)
------------------------------	---------------------	-----------------------	-----------------------

Order Providers

Authorizing Provider	Encounter Provider
----------------------	--------------------

Collection Information

Date and Time	Accession #
---------------	-------------

Priority and Order Details

Priority Routine	Class
---------------------	-------

Criteria	lw 1/21/14	Yes	No
Dual/Synchronous Primary	Noted		✓

Source: NCI Genomic Data Commons file 63c2f167-3477-4929-9ac3-85f80946d291 (TCGA-GU-AATP.6E966861-6052-4F99-8BD5-0835BAE0179D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).